Somatic mutation profile of tumor specimen TCGA-HU-A4H0-01A (aliquot TCGA-HU-A4H0-01A-11D-A25D-08) from TCGA case TCGA-HU-A4H0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.1 years (26,317 days).
Specimen TCGA-HU-A4H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12457c29-a67c-42d6-9d02-fa209060348e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H0-11A (Solid Tissue Normal), aliquot TCGA-HU-A4H0-11A-11D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/764fef5d-a44d-49cc-9308-1363b2716a34

The open-access MAF lists 188 somatic variants for this specimen: 134 protein-altering or splice-affecting, 47 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 47, Nonsense Mutation 6, RNA 3, Frame Shift Del 3, Frame Shift Ins 3, Intron 2, Splice Site 2, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.13194_13197del p.D4398Efs*16 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | catalogued as rs727502971; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 16/29 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913468, COSV54062373, COSV54062425, COSV54063143; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RHOA | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV69041855; called by muse, mutect2, varscan2
- ADGRB3 | c.3001T>G p.F1001V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53236828, COSV53240687; called by muse, mutect2, varscan2
- ADNP2 | c.671C>G p.A224G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV51536663; called by muse, mutect2, varscan2
- AFDN | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60039038; called by muse, mutect2, varscan2
- AHNAK | c.8098A>G p.M2700V | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs1256650857, COSV57205685; called by muse, mutect2
- AP4E1 | c.1723A>T p.I575F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV55915447; called by muse, mutect2, varscan2
- AREL1 | c.1100T>G p.F367C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62665641; called by muse, mutect2, varscan2
- ARHGEF7 | c.440C>T p.S147L (on ENST00000375741 / NM_001113511.2; = p.S126L on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.407); catalogued as rs750993031, COSV54541804, COSV54543563; called by muse, mutect2, varscan2
- ASNSD1 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53623059; called by muse, mutect2, varscan2
- ATXN2 | c.3107C>T p.T1036M (on ENST00000550104; = p.T876M on NM_002973.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs745882036, COSV66481677; called by muse, mutect2, varscan2
- BCL9 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs782019322, COSV52341736; called by muse, mutect2, varscan2
- CACNA1G | c.4424C>G p.A1475G | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61721134; called by muse, mutect2, varscan2
- CACNA1H | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV61985225; called by muse, mutect2, varscan2
- CAND1 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV73338552; called by muse, mutect2, varscan2
- CDH10 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as rs770889275, COSV52572277, COSV52589543; called by muse, mutect2, varscan2
- CDH20 | c.1070A>C p.N357T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769890890, COSV53005701; called by muse, mutect2, varscan2
- CIR1 | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59595366; called by muse, mutect2
- CLDN12 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV55306334; called by muse, mutect2, varscan2
- CLIC5 | c.682G>A p.G228S (on ENST00000185206 / NM_001370649.1; = p.G69S on NM_016929.5) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs372834840; called by muse, mutect2, varscan2
- CNGB3 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV60685819; called by muse, mutect2
- CNTN6 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV100610157; called by muse, mutect2
- CR2 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65506306; called by muse, mutect2, varscan2
- CREBBP | c.4624G>A p.G1542S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52115796; called by muse, mutect2, varscan2
- CTNNBL1 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs767022909, COSV63743968; called by muse, mutect2, varscan2
- DACH1 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV57521787; called by muse, mutect2
- DCAF4L2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs865992251, COSV60477474, COSV60477956; called by muse, mutect2, varscan2
- DHRS9 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1396015109, COSV59139019; called by muse, mutect2, varscan2
- DMD | c.4751C>A p.T1584K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV63738618; called by muse, mutect2, varscan2
- DNAI2 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1241205365, COSV56757203; called by muse, mutect2, varscan2
- DVL2 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs780644904, COSV50034590; called by muse, mutect2, varscan2
- EFCAB5 | c.4138C>T p.R1380C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs754404201, COSV57926755; called by muse, mutect2, varscan2
- ELAVL4 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV63914820; called by muse, mutect2, varscan2
- FAT4 | c.10197T>A p.D3399E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58674185; called by muse, mutect2, varscan2
- FGF12 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV53152374, COSV53155258, COSV53158085; called by muse, mutect2, varscan2
- FGF17 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV63925379; called by muse, mutect2, varscan2
- FPR3 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781059093, COSV59328534; called by muse, mutect2, varscan2
- FST | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV56815019; called by muse, mutect2, varscan2
- GAB4 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs1234053003, COSV68753147; called by muse, mutect2, varscan2
- GABRG2 | c.908C>T p.S303F (on ENST00000361925 / NM_001375343.1; = p.S263F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV62715890; called by muse, mutect2, varscan2
- GRIP1 | c.2804T>A p.M935K (on ENST00000359742 / NM_001379345.1; = p.M883K on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV54016858; called by muse, mutect2, varscan2
- HDAC9 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV67768391; called by muse, mutect2, varscan2
- HEBP2 | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62928121; called by muse, mutect2, varscan2
- HIVEP3 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746529841, COSV56010759; called by muse, mutect2, varscan2
- HPSE2 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65182415; called by muse, mutect2
- HSPG2 | c.4863G>T p.E1621D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.987); catalogued as COSV65969534; called by muse, mutect2, varscan2
- INO80D | c.2566A>G p.M856V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs765674194, COSV68958259; called by muse, mutect2, varscan2
- IQCN | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV66572794; called by muse, mutect2
- IRS4 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV64532867; called by muse, mutect2
- IRX5 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767836036, COSV58058503; called by muse, mutect2, varscan2
- JAKMIP2 | c.1713A>T p.Q571H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54598827; called by muse, mutect2, varscan2
- KHDC3L | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV64859042; called by muse, mutect2
- KNL1 | c.2362A>G p.M788V (on ENST00000346991 / NM_170589.5; = p.M762V on NM_144508.5) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1013985737, COSV61151970; called by muse, mutect2
- LONP2 | c.2528C>T p.T843I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); catalogued as COSV53520934; called by muse, mutect2
- LRFN3 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as rs747501966, COSV55816958, COSV55817098; called by muse, mutect2, varscan2
- LRIT2 | c.1184C>T p.T395I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1212042681, COSV60560049; called by muse, mutect2, varscan2
- LTA | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV69304218; called by muse, mutect2, varscan2
- LYN | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101319599, COSV70205399; called by muse, mutect2, varscan2
- MAST1 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52242179; called by muse, mutect2, varscan2
- MED12L | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs774424420, COSV56370763; called by muse, mutect2, varscan2
- MEGF6 | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs774154218, COSV53886917; called by muse, mutect2, varscan2
- MEGF8 | c.6553G>A p.G2185R (on ENST00000251268 / NM_001271938.2; = p.G2118R on NM_001410.3) | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1183931335, COSV52073707; called by muse, mutect2, varscan2
- MITD1 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV56806068; called by muse, mutect2, varscan2
- MKRN3 | c.1306G>T p.G436W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58808952; called by muse, mutect2, varscan2
- MYBPC3 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs397515939, CM115897, COSV57024001; ClinVar: uncertain significance; called by muse, mutect2
- MYH7 | c.4052C>T p.T1351M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs370403289, CM068017; ClinVar: uncertain significance; called by mutect2, varscan2
- MYH9 | c.1683G>T p.Q561H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV53382826; called by muse, mutect2, varscan2
- NCKAP5 | c.1480C>A p.Q494K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58430982; called by muse, mutect2, varscan2
- NCSTN | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV54185323; called by muse, mutect2, varscan2
- NELFCD | c.1576C>T p.R526* (on ENST00000602795; = p.R508* on NM_198976.4) | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as rs1288162314, COSV53882585; called by muse, mutect2, varscan2
- NR2F1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV59067745; called by muse, mutect2, varscan2
- NRXN3 | c.1511A>T p.K504I (on ENST00000335750 / NM_001330195.2; = p.K131I on NM_004796.6) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59720546; called by muse, mutect2, varscan2
- NUAK1 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54601082; called by muse, mutect2, varscan2
- OR1C1 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV68715471; called by mutect2, varscan2
- OR1C1 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68715475; called by mutect2, varscan2
- OR4C46 | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100060487, COSV60218516; called by muse, mutect2, varscan2
- PCDH10 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52088653; called by muse, mutect2, varscan2
- PCDHGA5 | c.1277A>G p.D426G | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53909483; called by muse, mutect2, varscan2
- PCDHGC4 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52745323; called by muse, mutect2, varscan2
- PIK3CA | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs202013300, COSV55889280; called by muse, mutect2, varscan2
- PIK3R2 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55846981; called by muse, mutect2
- PIWIL3 | c.1732A>G p.K578E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as COSV59993888; called by muse, mutect2, varscan2
- PKD1L1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs141974473; called by mutect2, varscan2
- PLA2G3 | c.997A>G p.M333V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762780314, COSV53208137; called by muse, mutect2
- PLCB4 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV53795088; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57963207; called by muse, mutect2, varscan2
- POU2F3 | c.133-2A>G p.X45_splice | Splice Site (SNP) | VAF 48/228 reads (21%) | catalogued as COSV52792546; called by muse, mutect2, varscan2
- POU3F2 | c.933T>A p.F311L | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60408554; called by muse, mutect2, varscan2
- POU4F3 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196270089, COSV57942641; called by muse, mutect2, varscan2
- PRDM16 | c.2911A>T p.R971W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54581163; called by muse, mutect2, varscan2
- PRDM9 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs763283811, COSV57003405; called by muse, mutect2, varscan2
- PRKCE | c.503A>T p.N168I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV60314050; called by muse, mutect2, varscan2
- PSD | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs761558318, COSV50042339; called by muse, mutect2, varscan2
- PSD2 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV51197388; called by muse, mutect2, varscan2
- RDH12 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50821455; called by muse, mutect2, varscan2
- RECQL5 | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs760175418, COSV58638118; called by muse, mutect2, varscan2
- REV3L | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62616060; called by muse, mutect2, varscan2
- ROCK1 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV67694773; called by muse, mutect2, varscan2
- SCUBE2 | c.2849A>G p.Y950C (on ENST00000649792 / NM_001367977.2; = p.Y893C on NM_020974.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376004700; called by muse, mutect2, varscan2
- SDR9C7 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1237692044, COSV53288540; called by muse, mutect2, varscan2
- SDSL | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61884285; called by muse, mutect2
- SEMA4G | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs764503702, COSV52966682; called by mutect2, varscan2
- SERPINB5 | c.1044G>C p.L348F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66975042; called by muse, mutect2, varscan2
- SIGLEC8 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs141833256; called by muse, mutect2, varscan2
- SLC25A13 | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55704361; called by muse, mutect2, varscan2
- SLC2A10 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV63713834; called by muse, mutect2, varscan2
- SLITRK2 | c.1106A>T p.D369V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV59423539; called by muse, mutect2, varscan2
- SLITRK6 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs369304860; called by muse, mutect2, varscan2
- SOX30 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs760251674, COSV53936356, COSV99398724; called by mutect2, varscan2
- SOX30 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV53936360; called by muse, mutect2, varscan2
- SPATA5L1 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59744059, COSV59744209; called by muse, mutect2, varscan2
- STAT1 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63115234; called by muse, mutect2, varscan2
- STXBP5L | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1483346314, COSV56502913; called by muse, mutect2
- TMEM132D | c.2594A>C p.K865T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101242707, COSV67158649; called by mutect2, varscan2
- TOGARAM2 | c.2947C>T p.L983F | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65420151; called by muse, mutect2
- UBE3B | c.1457C>T p.T486I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV55091710; called by muse, mutect2
- ULK1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs138390533; called by muse, mutect2, varscan2
- VPS13B | c.7544A>G p.N2515S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV62135133; called by muse, mutect2, varscan2
- VPS37A | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as rs778809661, COSV61364278; called by muse, mutect2
- WASF3 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV58963222; called by muse, mutect2, varscan2
- WSCD2 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1379043488, COSV54578928; called by muse, mutect2, varscan2
- ZBTB41 | c.986A>G p.N329S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as COSV66358793; called by muse, mutect2, varscan2
- ZGPAT | c.873G>C p.V291= | Splice Region (SNP) | VAF 18/168 reads (11%) | catalogued as COSV58873542; called by muse, mutect2, varscan2
- ZNF343 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as rs143248617; called by muse, mutect2, varscan2
- ZNF609 | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs202246854, COSV58580467; called by muse, mutect2, varscan2
- CCDC9 | c.1423dup p.E475Gfs*30 | Frame Shift Ins (INS) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- DSG2 | c.375dup p.L126Sfs*23 | Frame Shift Ins (INS) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- LGALS2 | c.85del p.D29Mfs*4 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- NPAP1 | c.2922T>A p.N974K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH9 | c.2579del p.N860Tfs*23 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- RSPRY1 | c.479dup p.T161Nfs*6 | Frame Shift Ins (INS) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- SGIP1 | c.99+4_99+7del p.X33_splice | Splice Site (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- SYNE2 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- AFF2 | c.3276A>G p.K1092= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53979384; called by muse, mutect2, varscan2
- AHNAK | c.4566C>T p.G1522= | Silent (SNP) | VAF 25/173 reads (14%) | catalogued as COSV57205694; called by muse, mutect2, varscan2
- CD180 | c.1803C>T p.G601= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs1294797989, COSV56517056; called by muse, mutect2, varscan2
- CHAT | c.717C>T p.I239= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV60321043; called by muse, mutect2, varscan2
- CHRNA4 | c.138C>T p.S46= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs200705061, COSV64717400; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CLEC4E | c.324C>T p.C108= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs376364851; called by mutect2, varscan2
- CLNS1A | c.153A>G p.G51= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1270124866, COSV54439547; called by muse, mutect2, varscan2
- CPEB1 | c.1464C>A p.P488= (on ENST00000617958; = p.P423= on NM_030594.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV55617512; called by muse, mutect2, varscan2
- CUBN | c.4110C>T p.L1370= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV64709320; called by muse, mutect2, varscan2
- CYP4A22 | c.993C>T p.S331= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1329545340, COSV53738588; called by muse, varscan2
- DPYSL4 | c.120C>A p.G40= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- EPB41L3 | c.2577G>A p.E859= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV59446242; called by muse, mutect2, varscan2
- FFAR1 | c.240C>T p.P80= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV50049907; called by muse, mutect2
- FOXJ1 | c.561C>T p.D187= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs754084474, COSV53942405; called by muse, mutect2
- GCN1 | c.399G>A p.K133= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV56104661; called by muse, mutect2, varscan2
- GLIS2 | c.438C>T p.A146= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1331400191, COSV52109528; called by muse, mutect2, varscan2
- GPR152 | c.939C>T p.F313= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs144851549; called by muse, mutect2, varscan2
- GRID1 | c.996C>T p.N332= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs368514571, COSV60016794, COSV60044062; called by muse, mutect2, varscan2
- HEATR1 | c.3594A>G p.E1198= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs149288116; called by muse, mutect2, varscan2
- IGHV1-45 | c.132C>T p.S44= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs782762659; called by muse, mutect2, varscan2
- KCNA4 | c.633C>T p.Y211= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV60250944; called by muse, mutect2
- KLHL31 | c.1386G>C p.A462= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs750382766, COSV63881525; called by muse, mutect2
- MCF2 | c.658C>T p.L220= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58479296; called by muse, mutect2, varscan2
- MEF2C | c.1296C>T p.D432= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs756839313, COSV60925026; called by muse, mutect2, varscan2
- MUC20 | c.516G>T p.L172= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV57847998; called by mutect2, varscan2
- NCOR1 | c.4485C>T p.G1495= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV51963824; called by muse, mutect2, varscan2
- NFS1 | c.489C>T p.C163= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as COSV60763938; called by muse, mutect2, varscan2
- NRG3 | c.1758C>T p.D586= (on ENST00000404547 / NM_001370084.1; = p.D562= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV64548006; called by muse, mutect2, varscan2
- OR13C8 | c.357A>G p.A119= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV58610634; called by muse, mutect2
- OR5W2 | c.351G>A p.V117= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100747685, COSV60614915; called by muse, mutect2, varscan2
- POU4F3 | c.219G>A p.P73= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV57942378, COSV57942627; called by muse, mutect2, varscan2
- PTPRU | c.3150G>A p.A1050= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs745686767, COSV60523030; called by muse, mutect2, varscan2
- RASGRF2 | c.864C>T p.D288= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs368702145; called by muse, mutect2, varscan2
- RECQL | c.120A>G p.K40= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV59084411; called by muse, mutect2, varscan2
- RPN2 | c.1461T>C p.D487= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52904160; called by muse, mutect2, varscan2
- SESTD1 | c.783C>T p.Y261= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV58930423; called by muse, mutect2, varscan2
- SNAP91 | c.2544C>T p.G848= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV52117122; called by muse, mutect2, varscan2
- SPTA1 | c.636G>A p.G212= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1190774456, COSV100934401, COSV63749830; called by muse, mutect2, varscan2
- TET1 | c.1317A>G p.P439= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV65382565; called by muse, mutect2, varscan2
- TMEM63C | c.1431C>T p.L477= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs757088743, COSV53601758; called by muse, mutect2, varscan2
- TOX3 | c.1137C>T p.L379= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as rs566980343, COSV54863478; called by muse, mutect2, varscan2
- UBE4B | c.3252C>A p.R1084= (on ENST00000343090 / NM_001105562.3; = p.R955= on NM_006048.5) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99477583; called by muse, mutect2, varscan2
- UMODL1 | c.168G>A p.T56= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs373713727; called by muse, mutect2, varscan2
- VARS2 | c.156A>G p.R52= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52558026; called by muse, mutect2, varscan2
- ZNF345 | c.487C>A p.R163= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV59322824; called by muse, mutect2, varscan2
- ZNF423 | c.2934G>A p.S978= (on ENST00000563137 / NM_001379286.1; = p.S970= on NM_015069.4) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1182844306, COSV52179495; called by muse, mutect2, varscan2
- ZNF74 | c.126G>A p.S42= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs555284841, COSV62620239; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840291 G>A | 5'Flank (SNP) | VAF 24/105 reads (23%) | catalogued as COSV58329215, COSV58347136; called by muse, mutect2, varscan2
- DCHS2 | n.4552C>A | RNA (SNP) | VAF 10/57 reads (18%) | catalogued as COSV61768779; called by muse, mutect2, varscan2
- KIF1B | c.2115+6133A>G | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- MMP16 | c.1222+5093C>T | Intron (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99686579; called by muse, mutect2, varscan2
- PARGP1 | n.283A>T | RNA (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- SSPOP | n.7062C>T | RNA (SNP) | VAF 3/18 reads (17%) | catalogued as COSV50486635; called by muse, mutect2
- TEX101 | c.-17C>T | 5'UTR (SNP) | VAF 33/241 reads (14%) | catalogued as rs759736291; called by muse, mutect2, varscan2
